Somatic mutation profile of tumor specimen TARGET-15-SJMPAL044956-09A (aliquot TARGET-15-SJMPAL044956-09A-01D) from TARGET case TARGET-15-SJMPAL044956, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.0 years (5,108 days).
Specimen TARGET-15-SJMPAL044956-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3f9e0405-375d-4fb3-a632-41be4f06673c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL044956-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL044956-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9283fac8-b428-42c1-9f0d-ddd9f4ba6ed8

The open-access MAF lists 15 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, RNA 1, 3'UTR 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 21/40 reads (53%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ALDH1A1 | c.203G>A p.R68K | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.18); catalogued as rs1442833819; called by muse, mutect2
- CACNA1A | c.1160G>A p.R387H | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs184473835; called by muse, mutect2, varscan2
- CFAP47 | c.1005A>C p.Q335H | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.14); PolyPhen benign (0.089); catalogued as COSV52887478; called by muse, mutect2, varscan2
- FZD9 | c.893C>A p.A298E | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.167); catalogued as COSV60669825; called by muse, mutect2
- OTX2 | c.116G>T p.R39L (on ENST00000408990 / NM_172337.3; = p.R47L on NM_021728.4) | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100257927; called by muse, mutect2
- ADAMTS9 | c.493G>T p.V165F | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PALM2AKAP2 | c.917C>A p.A306E (on ENST00000259318 / NM_001136562.3; = p.A537E on NM_007203.5) | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.033); called by muse, mutect2
- NXPE4 | c.507G>C p.L169= | Silent (SNP) | VAF 30/58 reads (52%) | called by muse, mutect2, varscan2
- RPTOR | c.1206G>A p.A402= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs747216581, COSV60820672; called by muse, mutect2, varscan2
- TLE6 | c.1215C>A p.I405= (on ENST00000246112 / NM_001143986.2; = p.I282= on NM_024760.3) | Silent (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- USP45 | c.1905G>T p.G635= | Silent (SNP) | VAF 4/36 reads (11%) | called by muse, varscan2
- CPLANE1 | c.*4338G>T | 3'UTR (SNP) | VAF 3/18 reads (17%) | called by muse, mutect2
- MIR663B | n.104G>T | RNA (SNP) | VAF 5/43 reads (12%) | catalogued as rs1416760616; called by muse, mutect2, varscan2
- RHPN2 | c.-6G>T | 5'UTR (SNP) | VAF 5/75 reads (7%) | called by muse, mutect2
